Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACO-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : LIVER HCC

Gross Photo :

GROSS:

Specimen:

Liver: 4.3 x 3.6 x 3.1 cm, unfixed

Tumor location: Center of the specimen

Tumor number: One

Tumor size: 2.5 x 2.4 x 2.3 cm

Satellite nodule: No

Gross type

HCC: Expanding nodular

Tumor necrosis: Yes (20 %)

Hemorrhage/peliosis: No

Portal vein invasion: Unknown

Bile duct invasion: Unknown

Peritumoral cirrhosis, micronodular

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site Liver C22.0

MD 5/19/14

Gross photo present.

Blocks

T1-4 and A, mass and surrounding tissue x 5

L, remaining liver x 1

MICROSCOPIC:

Hepatocellular carcinoma: yes

Differentiation

The worst differentiation: III

The major differentiation: II

Histologic type: trabecular and solid

Cell type: hepatic

Fatty change: no

Fibrous capsule formation: partial

Capsular infiltration: no

Septum formation: yes

Surgical resection margin invasion: no (safety margin :1.0 mm)

Serosal invasion: no

Portal vein invasion: no

Bile duct invasion: no

Hepatic vein invasion: no

Hepatic artery invasion: no

Microvessel invasion: no

[page 2 of 2]
Intrahepatic metastasis: no
Multicentric occurrence: no

Non-tumor liver pathology

Chronic hepatitis: yes
Etiology: HBV
Grade, lobular: minimal (grade 1)
Grade, portoperiportal: mild (grade 2)
Stage (fibrosis): cirrhosis (stage 4)
Dysplastic nodule: no
Ductal epithelial dysplasia: no
Other liver diseases: steatosis, mild

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, cirrhosis, steatosis
T56000, P10, M81703, M49500, M50080

DIAGNOSIS:

Liver, segment 7, subsegmentectomy:
Hepatocellular carcinoma, moderately differentiated
Cirrhosis
Steatosis, mild

Suggestion :

Source: NCI Genomic Data Commons file a7da2d79-0a1b-4d75-9c5f-bfee53b21889 (TCGA-DD-AACO.B5BE83AC-C974-422B-91E7-A69057BA26C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).